Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042789-09A.1 (aliquot TARGET-15-SJMPAL042789-09A.1-01D) from TARGET case TARGET-15-SJMPAL042789, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,371 days).
Specimen TARGET-15-SJMPAL042789-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7afc688f-92c1-4c59-80c9-6ce3d7bf97d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042789-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042789-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25a20d9d-b9d2-4122-b2b4-e86852daf5bf

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP295 | c.431C>A p.T144N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, mutect2
- ZNF250 | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- GOLGA8O | c.507C>T p.R169= | Silent (SNP) | VAF 31/165 reads (19%) | catalogued as rs778644601; called by muse, mutect2, varscan2
